Somatic mutation profile of tumor specimen C3N-00168-03 (aliquot CPT0020000009) from CPTAC case C3N-00168, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.5 years (17,349 days).
Specimen C3N-00168-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 896d312d-040e-4e9f-ba08-eecf2fbedcff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00168-31 (Blood Derived Normal), aliquot CPT0020920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b00bf4b-faf2-496e-a12a-2d6aad75b18b

The open-access MAF lists 49 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Intron 3, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1709G>A p.R570Q (on ENST00000372530 / NM_001198934.2; = p.R527Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/198 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745844891, COSV55085418; called by muse, mutect2
- ADTRP | c.197T>A p.V66E | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57643443; called by muse, mutect2, varscan2
- CDHR5 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748626313; called by muse, mutect2
- DMXL1 | c.5510A>T p.H1837L | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as rs564680072; called by muse, mutect2
- EPHX2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867470047; called by muse, mutect2
- GLI2 | c.1970C>A p.A657D (on ENST00000361492 / NM_001374353.1; = p.A674D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs773562626; called by muse, mutect2, varscan2
- KDM3B | c.3343C>T p.R1115W | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287032605, COSV58692920; called by muse, mutect2
- PDPN | c.329C>T p.T110M (on ENST00000621990; = p.T186M on NM_006474.4) | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs368396279; called by muse, mutect2, varscan2
- PRDM14 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs889482883; called by muse, mutect2
- RNF133 | c.857G>A p.W286* | Nonsense Mutation (SNP) | VAF 16/133 reads (12%) | catalogued as rs1224943125; called by muse, mutect2, varscan2
- ACTB | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 59/556 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CUBN | c.865T>C p.C289R | Missense Mutation (SNP) | VAF 69/708 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DHFR2 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- GANC | c.224A>C p.Y75S | Missense Mutation (SNP) | VAF 11/156 reads (7%) | PolyPhen benign (0.001); called by muse, mutect2
- HIVEP2 | c.2025G>A p.M675I | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- HOOK3 | c.858T>G p.N286K | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- IL21 | c.360+1G>C p.X120_splice | Splice Site (SNP) | VAF 8/74 reads (11%) | called by muse, varscan2
- ITGA2 | c.2726G>C p.S909T | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- ITPR2 | c.4588A>C p.K1530Q | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2
- JAG2 | c.3115A>C p.S1039R | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIAA0232 | c.722_732del p.T241Rfs*16 | Frame Shift Del (DEL) | VAF 24/254 reads (9%) | called by mutect2, pindel
- MUC17 | c.11918C>A p.T3973K | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- NEGR1 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 34/439 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.3); called by muse, mutect2
- NIPAL4 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51I2 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OVCH1 | c.841T>A p.F281I | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- P3H3 | c.1850A>G p.D617G | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.9); called by muse, mutect2
- RRP9 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SEPTIN5 | c.380A>C p.D127A | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- SLFN12L | c.1037C>T p.P346L (on ENST00000260908 / NM_001363830.1; = p.P364L on NM_001195790.1) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, varscan2
- SPNS1 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- VCAM1 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- WDSUB1 | c.1428G>T p.K476N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- YWHAQ | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.53); called by muse, mutect2
- ZNF407 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- ZNF91 | c.2548G>T p.G850* | Nonsense Mutation (SNP) | VAF 25/195 reads (13%) | called by muse, mutect2, varscan2
- ZSWIM7 | c.188_195del p.R63Ifs*9 | Frame Shift Del (DEL) | VAF 18/170 reads (11%) | called by mutect2, pindel
- AHSG | c.534C>T p.S178= | Silent (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- COL26A1 | c.318C>T p.S106= (on ENST00000313669 / NM_001278563.3; = p.S104= on NM_133457.4) | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV58128590; called by muse, mutect2
- DOCK6 | c.252G>A p.E84= | Silent (SNP) | VAF 16/89 reads (18%) | called by mutect2, varscan2
- NAV2 | c.2430G>A p.Q810= (on ENST00000396087 / NM_001244963.2; = p.Q787= on NM_145117.5) | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV62337380; called by muse, mutect2, varscan2
- PTPRT | c.1620G>T p.G540= | Silent (SNP) | VAF 34/402 reads (8%) | catalogued as COSV61961508; called by muse, mutect2
- RALYL | c.144A>C p.I48= | Silent (SNP) | VAF 25/244 reads (10%) | called by muse, mutect2, varscan2
- SLC12A5 | c.507G>A p.T169= (on ENST00000454036 / NM_001134771.2; = p.T146= on NM_020708.5) | Silent (SNP) | VAF 13/174 reads (7%) | catalogued as rs1345353699; called by muse, mutect2
- SORBS2 | c.846G>T p.V282= (on ENST00000284776 / NM_021069.5; = p.V375= on NM_003603.6) | Silent (SNP) | VAF 42/339 reads (12%) | called by muse, mutect2, varscan2
- ZFAND3 | c.441T>C p.S147= | Silent (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- NALCN | c.2118+16del | Intron (DEL) | VAF 18/194 reads (9%) | called by mutect2, pindel
- NDUFC2-KCTD14 | c.311-21440C>T | Intron (SNP) | VAF 32/329 reads (10%) | catalogued as rs1440788637; called by muse, mutect2
- SLIT3 | c.1008-14G>C | Intron (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2
